CPTAC case C3N-01505 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/da2fcf60-1e83-4d6b-8527-702bf3e2c2dc

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1942; Vital status: Dead; Days to death: 192 days; Year of death: 2017; Cause of death: Not Cancer Related; Country of birth: Croatia.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Parietal lobe; Age at diagnosis: 74.3 years (27,131 days); Year of diagnosis: 2017; Last known disease status: With tumor; Days to last known disease status: 192 days; Progression or recurrence: yes; Days to recurrence: 189 days; Days to last follow up: 192 days.
   Pathology details: Greatest tumor dimension: 1.2 cm.

Follow-up (1 entry)
- Days to follow up: 192 days; Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 189 days; Karnofsky performance status: 0.

Other clinical attributes
- Weight: 79.83 kg; Height: 175.26 cm; BMI: 25.99.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-01505-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 228 mg; Time between excision and freezing: 7 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01505-21: Section location: Parietal Lobe; Percent tumor nuclei: 75; Percent necrosis: 10.
- Sample C3N-01505-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
- Sample C3N-01505-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
